Somatic mutation profile of tumor specimen MBCProject_0217_T1_WES (aliquot MBCProject_0217_T1_WES_1) from CMI case MBCProject_0217, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 56.9 years (20,800 days).
Specimen MBCProject_0217_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3c53dfc-22c2-42f6-9be0-57be073423a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0217_SALIVA (Saliva), aliquot MBCProject_0217_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7c02f9b-cfdf-491c-82cb-1d677ba1e861

The open-access MAF lists 45 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 12, 5'Flank 2, Frame Shift Del 2, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 71/221 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2820A>C p.E940D | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.93); catalogued as COSV70025519, COSV70028233; called by muse, mutect2, varscan2
- AOC1 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs374705415; called by muse, mutect2, varscan2
- CXCR1 | c.280A>T p.I94F | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55283117; called by muse, mutect2
- DNAH11 | c.13070G>A p.R4357Q | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs369549112, COSV60963912; called by muse, mutect2, varscan2
- FRAS1 | c.5126G>A p.R1709Q | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs763116888, COSV99356444; called by muse, mutect2, varscan2
- KCNMA1 | c.3740C>T p.P1247L | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.189); catalogued as rs202009916; called by muse, mutect2
- KIF5A | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs537001094, COSV54057612; called by muse, mutect2, varscan2
- METTL27 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs370364417; called by muse, mutect2
- OR2T33 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV58815643; called by mutect2, varscan2
- OR4A15 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.101); catalogued as COSV59033609; called by muse, mutect2, varscan2
- PCNX4 | c.925C>T p.P309S (on ENST00000406854 / NM_001330177.2; = p.P75S on NM_022495.5) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV58302398; called by muse, varscan2
- RAB40AL | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1294860061, COSV54434988, COSV54435453; called by muse, mutect2
- SGSH | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775112689, CM971360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.13799T>C p.V4600A (on ENST00000591111; = p.V3673A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/145 reads (8%) | PolyPhen probably damaging (0.99); catalogued as COSV100636289; called by muse, mutect2
- BCL10 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLEC12A | c.61del p.I21Sfs*26 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- IMP4 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- INTS6 | c.2049del p.A684Hfs*27 | Frame Shift Del (DEL) | VAF 44/280 reads (16%) | called by mutect2, pindel, varscan2
- MCM8 | c.313A>G p.R105G | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIB1 | c.2475G>A p.M825I | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MIOS | c.549G>C p.Q183H | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.892); called by muse, mutect2
- PCDH7 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- PKDREJ | c.4109A>G p.H1370R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- RADIL | c.2954G>A p.G985E | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTF2 | c.636T>A p.D212E | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STRIP2 | c.1878C>A p.S626R | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF541 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- BFSP2 | c.306G>A p.E102= | Silent (SNP) | VAF 29/267 reads (11%) | called by muse, mutect2, varscan2
- CDC7 | c.903G>A p.E301= | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as rs370367545, COSV52310044; called by muse, mutect2, varscan2
- EEF1G | c.603G>C p.R201= | Silent (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- GFOD1 | c.63G>A p.L21= | Silent (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- LRRC75A | c.888C>T p.P296= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as rs1408398071; called by muse, mutect2
- MATN4 | c.1269G>A p.T423= (on ENST00000372754; = p.T382= on NM_003833.4) | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV100636958; called by muse, mutect2, varscan2
- SERPINB10 | c.1119T>C p.N373= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV53071945; called by muse, mutect2, varscan2
- SLC25A21 | c.111G>A p.V37= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV58717662; called by muse, mutect2, varscan2
- ST13 | c.474C>T p.F158= | Silent (SNP) | VAF 21/210 reads (10%) | catalogued as rs764960231, COSV53423031; called by muse, mutect2, varscan2
- TATDN3 | c.339C>A p.S113= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV65324715; called by muse, mutect2, varscan2
- TRAV8-3 | c.156C>G p.L52= | Silent (SNP) | VAF 34/225 reads (15%) | called by muse, mutect2, varscan2
- ZNF678 | c.615A>T p.G205= | Silent (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- ACAA2 | chr18:49814038 C>G | 5'Flank (SNP) | VAF 57/124 reads (46%) | catalogued as rs759100378; called by muse, mutect2
- EMD | c.265+24C>T | Intron (SNP) | VAF 8/159 reads (5%) | catalogued as rs1308579752; called by muse, mutect2
- FAM124A | c.834+14G>A | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as rs757705406, COSV54477954; called by muse, mutect2
- GNG5P2 | n.86C>G | RNA (SNP) | VAF 66/451 reads (15%) | called by muse, mutect2, varscan2
- PIP5K1A | chr1:151198036 G>A | 5'Flank (SNP) | VAF 26/74 reads (35%) | catalogued as rs908181098; called by muse, mutect2, varscan2
